Somatic mutation profile of tumor specimen TARGET-10-PANTBB-09A (aliquot TARGET-10-PANTBB-09A-01D) from TARGET case TARGET-10-PANTBB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,104 days).
Specimen TARGET-10-PANTBB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21d6a938-9329-4cb5-a155-6911c8e39d12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTBB-14A (Bone Marrow Normal), aliquot TARGET-10-PANTBB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b052004d-3868-4e99-9d8a-6f29715e3882

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Frame Shift Ins 1, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101201035, COSV67015773; called by mutect2, varscan2
- SEPTIN14 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV66429188; called by muse, varscan2
- SOWAHB | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100530764; called by muse, mutect2
- UBXN2A | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.367); catalogued as rs371669493; called by muse, mutect2, varscan2
- ZNF236 | c.5215C>A p.R1739S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99471070; called by muse, mutect2
- CRK | c.35G>T p.S12I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- DCAF12L2 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.134); called by muse, mutect2
- DYNC1H1 | c.1831C>A p.R611S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.949); called by muse, mutect2
- FBXO34 | c.908C>G p.S303* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- HTR3C | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- IGKV3-15 | c.196_197insCC p.L66Pfs*? | Frame Shift Ins (INS) | VAF 24/154 reads (16%) | called by mutect2*, pindel, varscan2
- IGKV3-15 | c.192_193del p.R65Afs*36 | Frame Shift Del (DEL) | VAF 35/131 reads (27%) | called by mutect2, varscan2*
- LRRK1 | c.3646C>A p.Q1216K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2
- ORC4 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by mutect2, varscan2
- PHKB | c.2675G>C p.G892A | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP4R4 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCNM1 | c.198G>C p.K66N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by mutect2, varscan2
- UBE2U | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- UBXN2A | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- USP19 | c.1732G>T p.A578S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- DST | c.12228G>A p.A4076= (on ENST00000361203 / NM_001374722.1; = p.A1664= on NM_015548.5) | Silent (SNP) | VAF 66/210 reads (31%) | catalogued as rs750764970; called by muse, mutect2, varscan2
- PCSK1 | c.528C>T p.D176= | Silent (SNP) | VAF 37/123 reads (30%) | called by muse, mutect2, varscan2
- PHTF1 | c.219G>C p.L73= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- PTF1A | c.*14C>G | 3'UTR (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22611230 G>C | 5'Flank (SNP) | VAF 33/115 reads (29%) | catalogued as rs752195965; called by muse, mutect2, varscan2
